Somatic mutation profile of tumor specimen TCGA-HT-7605-01A (aliquot TCGA-HT-7605-01A-11D-2086-08) from TCGA case TCGA-HT-7605, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Brain, NOS; Tumor grade: G2; Age at diagnosis: 38.0 years (13,892 days).
Specimen TCGA-HT-7605-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 035be2be-f7c9-4acd-94d4-3219d37cffc8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7605-10A (Blood Derived Normal), aliquot TCGA-HT-7605-10A-01D-2086-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/141da1bd-77ff-4625-8def-665539901ae9

The open-access MAF lists 29 somatic variants for this specimen: 22 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 18, Silent 7, Nonsense Mutation 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 33/104 reads (32%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACSM2A | c.153G>T p.L51F | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV54583382; called by muse, mutect2
- ASAP1 | c.137T>G p.F46C | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63046191; called by muse, mutect2, varscan2
- CORO2A | c.330G>T p.W110C | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59662609, COSV59664577; called by muse, mutect2, varscan2
- EFL1 | c.11A>G p.N4S | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs781182273, COSV51604187; called by muse, mutect2, varscan2
- FAM209A | c.422G>A p.S141N | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.682); catalogued as COSV54766506; called by muse, mutect2
- FBXO40 | c.131C>G p.A44G | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57522977; called by muse, mutect2
- FREM2 | c.4148T>C p.V1383A | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as COSV54832757; called by muse, mutect2
- GEMIN6 | c.175G>A p.G59R | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.944); catalogued as rs760437710, COSV56140233; called by muse, mutect2, varscan2
- HAS1 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.168); catalogued as rs759007645, COSV55786840; called by muse, mutect2, varscan2
- KANK3 | c.1723G>A p.A575T | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.095); catalogued as rs1363911311, COSV58359490; called by muse, mutect2
- KDM6B | c.3299C>A p.P1100H | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV54679578; called by muse, mutect2
- PIWIL2 | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV63250501; called by muse, mutect2
- PTPRU | c.312C>A p.Y104* | Nonsense Mutation (SNP) | VAF 24/244 reads (10%) | catalogued as COSV60524355; called by muse, mutect2
- RFX7 | c.2209C>T p.Q737* (on ENST00000559447 / NM_001368074.1; = p.Q834* on NM_022841.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 10/169 reads (6%) | catalogued as COSV57961381; called by muse, mutect2
- SH3BP5L | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | catalogued as COSV63538967; called by muse, mutect2
- SLC25A39 | c.343G>A p.V115M (on ENST00000377095 / NM_001143780.3; = p.V107M on NM_016016.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.094); catalogued as rs368381651, COSV56586792; called by muse, mutect2, varscan2
- TAF1 | c.3950G>T p.R1317L (on ENST00000373790 / NM_138923.4; = p.R1338L on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV52109777, COSV99333980; called by muse, mutect2, varscan2
- TANGO6 | c.865G>A p.V289M | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.254); catalogued as COSV55762587; called by muse, mutect2, varscan2
- TMEM131L | c.3731T>A p.F1244Y | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV53642433; called by muse, mutect2, varscan2
- UXS1 | c.547A>G p.T183A | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.993); catalogued as COSV51676217; called by muse, mutect2, varscan2
- FIP1L1 | c.1584_1585del p.H528Qfs*14 | Frame Shift Del (DEL) | VAF 10/51 reads (20%) | called by mutect2, pindel, varscan2
- ACTG2 | c.1026C>T p.I342= | Silent (SNP) | VAF 11/110 reads (10%) | catalogued as rs1422885943, COSV61827909; called by muse, mutect2, varscan2
- CACNA1G | c.1188G>A p.T396= | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as rs201089692, COSV61722607; called by muse, mutect2, varscan2
- CFAP91 | c.1935C>T p.S645= | Silent (SNP) | VAF 16/119 reads (13%) | catalogued as COSV56340038; called by muse, mutect2, varscan2
- CLIC4 | c.228A>G p.P76= | Silent (SNP) | VAF 13/95 reads (14%) | catalogued as COSV65525597; called by muse, mutect2, varscan2
- GIMAP5 | c.414T>C p.F138= | Silent (SNP) | VAF 17/146 reads (12%) | catalogued as rs776825281, COSV57529815; called by muse, mutect2, varscan2
- GPR162 | c.411C>T p.A137= | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as rs146153056, COSV50589809; called by muse, mutect2, varscan2
- MYH8 | c.3726C>T p.S1242= | Silent (SNP) | VAF 75/286 reads (26%) | catalogued as rs1230398276, COSV67962158; called by muse, mutect2, varscan2
